Somatic mutation profile of tumor specimen TCGA-85-A512-01A (aliquot TCGA-85-A512-01A-11D-A26M-08) from TCGA case TCGA-85-A512, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 46.0 years (16,811 days).
Specimen TCGA-85-A512-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) da39fb92-1bea-4c30-9e01-ef19eb8aa177.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-85-A512-10A (Blood Derived Normal), aliquot TCGA-85-A512-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eded02f2-b05e-469e-a2dc-cd5721959d59

The open-access MAF lists 177 somatic variants for this specimen: 133 protein-altering or splice-affecting, 39 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 112, Silent 39, Nonsense Mutation 10, Frame Shift Del 5, RNA 3, Frame Shift Ins 3, Splice Region 2, 5'UTR 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT3 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 8/74 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397514606, COSV55605820, COSV55624598; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.6756G>C p.Q2252H | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV100933145; called by muse, mutect2, varscan2
- ACER3 | c.185G>C p.R62P | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99568398; called by muse, mutect2
- ADAMTS12 | c.3969C>G p.S1323R | Missense Mutation (SNP) | VAF 47/77 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100711107; called by muse, mutect2, varscan2
- AEN | c.311G>T p.G104V | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.065); catalogued as COSV100237483; called by muse, varscan2
- ARHGAP35 | c.436G>C p.E146Q | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV101350798, COSV101351188; called by muse, mutect2, varscan2
- ASCC3 | c.1905G>T p.V635= | Splice Region (SNP) | VAF 57/79 reads (72%) | catalogued as COSV100225864; called by muse, mutect2, varscan2
- ASPA | c.594G>A p.M198I | Missense Mutation (SNP) | VAF 38/62 reads (61%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1380767447, COSV99559240; called by muse, mutect2, varscan2
- B4GALNT2 | c.326C>A p.P109Q | Missense Mutation (SNP) | VAF 59/163 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV100302580, COSV55925010; called by muse, mutect2, varscan2
- BIRC6 | c.4838C>A p.A1613D | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101428390; called by muse, mutect2, varscan2
- BRINP1 | c.1156C>A p.Q386K | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as COSV99775813; called by muse, mutect2, varscan2
- C10orf71 | c.650G>T p.G217V | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as COSV100110267, COSV60513078; called by muse, mutect2, varscan2
- C10orf90 | c.669G>A p.W223* | Nonsense Mutation (SNP) | VAF 34/84 reads (40%) | catalogued as COSV52957719; called by muse, mutect2, varscan2
- C12orf57 | c.250T>G p.L84V | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.607); catalogued as COSV99980771; called by muse, mutect2, varscan2
- CALCA | c.187G>T p.A63S | Missense Mutation (SNP) | VAF 37/58 reads (64%) | SIFT tolerated (0.05); PolyPhen benign (0.435); catalogued as COSV100524035; called by muse, mutect2, varscan2
- CALCR | c.490G>C p.V164L | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100810590; called by muse, mutect2, varscan2
- CATSPERG | c.2500T>C p.C834R | Missense Mutation (SNP) | VAF 49/77 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99286600; called by muse, mutect2, varscan2
- CD226 | c.189C>G p.F63L | Missense Mutation (SNP) | VAF 44/66 reads (67%) | SIFT tolerated (0.39); PolyPhen benign (0.187); catalogued as COSV54613507, COSV99711199; called by muse, mutect2, varscan2
- CD93 | c.1476C>A p.S492R | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV99849289; called by muse, mutect2, varscan2
- CD93 | c.361del p.E121Rfs*79 | Frame Shift Del (DEL) | VAF 10/14 reads (71%) | catalogued as rs762805003; called by mutect2, varscan2
- CDH9 | c.1081C>A p.L361M | Missense Mutation (SNP) | VAF 45/67 reads (67%) | SIFT tolerated (0.13); PolyPhen benign (0.05); catalogued as rs756492421, COSV99145698; called by muse, mutect2, varscan2
- CFAP47 | c.1015A>G p.K339E | Missense Mutation (SNP) | VAF 98/132 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99935193; called by muse, mutect2, varscan2
- CHD8 | c.1957G>T p.V653L (on ENST00000646647 / NM_001170629.2; = p.V374L on NM_020920.4) | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.229); catalogued as COSV101303151; called by muse, mutect2, varscan2
- CHPF2 | c.2177A>G p.Q726R | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.615); catalogued as rs767830975, COSV99223142; called by muse, mutect2, varscan2
- CNR1 | c.289C>A p.Q97K | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100759203; called by muse, mutect2, varscan2
- CSMD3 | c.2869C>T p.L957F (on ENST00000297405 / NM_001363185.1; = p.L853F on NM_052900.3) | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.999); catalogued as COSV52157753, COSV99824998, COSV99836689; called by muse, mutect2, varscan2
- CUBN | c.6402T>G p.F2134L | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100912849; called by muse, mutect2, varscan2
- DLC1 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 122/320 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.01); catalogued as rs1451783692, COSV99363556; called by muse, mutect2, varscan2
- DLG2 | c.1672C>T p.Q558* | Nonsense Mutation (SNP) | VAF 53/134 reads (40%) | catalogued as COSV99716697; called by muse, mutect2, varscan2
- DNAJC27 | c.21G>T p.K7N | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as COSV99266615; called by muse, mutect2
- DNAL4 | c.25G>T p.D9Y | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV99326137; called by muse, mutect2, varscan2
- DNMT1 | c.1610C>T p.P537L | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100532562; called by muse, mutect2, varscan2
- DPP10 | c.2087C>A p.S696Y | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); catalogued as COSV100067130; called by muse, mutect2, varscan2
- DPP6 | c.1468A>G p.I490V (on ENST00000377770 / NM_001364500.2; = p.I428V on NM_001936.5) | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as COSV100126022; called by muse, mutect2, varscan2
- DST | c.3207C>G p.I1069M (on ENST00000361203 / NM_001374722.1; = p.I743M on NM_001723.6) | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs754052746, COSV99757157; called by muse, mutect2, varscan2
- DYNC1H1 | c.3804G>C p.T1268= | Splice Region (SNP) | VAF 13/30 reads (43%) | catalogued as COSV100795012; called by muse, mutect2, varscan2
- ENTPD7 | c.1121G>A p.R374Q | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.148); catalogued as rs1209459742, COSV65112642; called by muse, mutect2, varscan2
- EPB41L3 | c.2791A>T p.S931C | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.572); catalogued as COSV100549443; called by muse, mutect2, varscan2
- EPHA4 | c.2291A>C p.D764A | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99916750, COSV99917906; called by muse, mutect2, varscan2
- EPHX3 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99650862; called by muse, mutect2
- ERGIC2 | c.62A>G p.K21R | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100791984; called by muse, mutect2, varscan2
- EYS | c.25C>A p.L9M | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.753); catalogued as COSV100676611; called by muse, mutect2, varscan2
- FAM135B | c.2334C>G p.S778R | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99424680; called by muse, varscan2
- FBXW7 | c.962G>A p.W321* (on ENST00000281708 / NM_001349798.2; = p.W241* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 59/82 reads (72%) | catalogued as COSV99657703; called by muse, mutect2, varscan2
- FRMPD3 | c.4469C>T p.A1490V | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs376134061, COSV99346466; called by muse, mutect2, varscan2
- GALNT13 | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs759879455, COSV101221753, COSV67229712; called by muse, mutect2, varscan2
- GBF1 | c.4690C>T p.Q1564* (on ENST00000369983 / NM_001377137.1; = p.Q1563* on NM_004193.3) | Nonsense Mutation (SNP) | VAF 134/334 reads (40%) | catalogued as COSV100890523; called by muse, mutect2, varscan2
- GCC1 | c.2077G>T p.E693* | Nonsense Mutation (SNP) | VAF 71/118 reads (60%) | catalogued as COSV100365552; called by muse, mutect2, varscan2
- GHRHR | c.605G>T p.C202F | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100396636; called by muse, mutect2, varscan2
- GRK5 | c.1692G>C p.K564N | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV100963094; called by muse, mutect2, varscan2
- GSTA1 | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 65/181 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as COSV100575546; called by muse, mutect2, varscan2
- HIVEP3 | c.3274G>T p.A1092S | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV99912906; called by muse, mutect2, varscan2
- HNRNPCL1 | c.409G>T p.A137S | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT tolerated (0.43); PolyPhen benign (0.074); catalogued as COSV100509016; called by muse, mutect2, varscan2
- IQGAP2 | c.1412G>A p.R471K | Missense Mutation (SNP) | VAF 46/80 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99167409; called by muse, mutect2, varscan2
- KCNK18 | c.1068G>C p.K356N | Missense Mutation (SNP) | VAF 57/181 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV100572064; called by muse, mutect2, varscan2
- KCNU1 | c.1732G>C p.V578L | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV101299273; called by muse, mutect2, varscan2
- KIF13B | c.2456C>A p.A819D | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.155); catalogued as COSV101568708; called by muse, mutect2, varscan2
- KMT2D | c.15095G>T p.C5032F | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99982787; called by muse, mutect2, varscan2
- KREMEN1 | c.631G>A p.V211M (on ENST00000407188; = p.V213M on NM_032045.5) | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.499); catalogued as rs377602415; called by muse, mutect2, varscan2
- LAMP5 | c.344A>G p.Y115C | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99855612; called by muse, mutect2, varscan2
- LRBA | c.3843G>T p.E1281D | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.003); catalogued as COSV100841703; called by muse, mutect2, varscan2
- LRBA | c.3057G>A p.M1019I | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV100841706; called by muse, mutect2, varscan2
- LRBA | c.2205C>G p.I735M | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100841708; called by muse, mutect2, varscan2
- MAGI2 | c.3589A>T p.I1197F | Missense Mutation (SNP) | VAF 84/359 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100834875; called by muse, mutect2, varscan2
- MKRN3 | c.982C>A p.R328S | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CM1512773, COSV100091280, COSV58811855; called by muse, mutect2, varscan2
- MORC1 | c.672G>T p.M224I | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV99226438; called by muse, mutect2, varscan2
- MYH13 | c.2481C>A p.N827K | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.049); catalogued as COSV99354276; called by muse, mutect2, varscan2
- NAP1L2 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 83/121 reads (69%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV65173026; called by muse, mutect2, varscan2
- NDUFB8 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.902); catalogued as rs765790228, COSV100144121; called by muse, mutect2, varscan2
- NLRP2 | c.2641G>A p.G881R | Missense Mutation (SNP) | VAF 43/64 reads (67%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.644); catalogued as rs866207869, COSV99672342; called by muse, mutect2, varscan2
- NPAP1 | c.309del p.N104Tfs*11 | Frame Shift Del (DEL) | VAF 21/57 reads (37%) | catalogued as COSV61505000; called by mutect2, pindel, varscan2
- NRG3 | c.1239G>A p.M413I | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.089); catalogued as COSV100931751; called by muse, mutect2, varscan2
- OR4C12 | c.99C>A p.Y33* | Nonsense Mutation (SNP) | VAF 28/86 reads (33%) | catalogued as COSV100078090; called by muse, mutect2, varscan2
- OR5W2 | c.677T>A p.L226* | Nonsense Mutation (SNP) | VAF 23/75 reads (31%) | catalogued as COSV100747650; called by muse, mutect2, varscan2
- OSBPL6 | c.2243A>T p.E748V | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99507664; called by muse, mutect2, varscan2
- PARD3B | c.3392A>T p.E1131V (on ENST00000406610 / NM_001302769.2; = p.E1062V on NM_057177.7) | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as rs760299104, COSV100593805; called by muse, mutect2, varscan2
- PCDH15 | c.5576A>T p.K1859M | Missense Mutation (SNP) | VAF 136/362 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.157); catalogued as COSV100222029, COSV57273219; called by muse, mutect2, varscan2
- PCDHGC5 | c.653G>T p.G218V | Missense Mutation (SNP) | VAF 37/65 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99340578; called by muse, mutect2, varscan2
- PGK1 | c.985A>C p.T329P | Missense Mutation (SNP) | VAF 37/61 reads (61%) | SIFT tolerated (0.18); PolyPhen benign (0.05); catalogued as COSV100540693; called by muse, mutect2, varscan2
- PKHD1 | c.4532C>A p.T1511N | Missense Mutation (SNP) | VAF 87/236 reads (37%) | SIFT tolerated (0.6); PolyPhen benign (0.255); catalogued as COSV100583400; called by muse, mutect2, varscan2
- POF1B | c.648C>G p.I216M | Missense Mutation (SNP) | VAF 52/82 reads (63%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.394); catalogued as COSV99426841; called by muse, mutect2, varscan2
- POGZ | c.3568A>G p.I1190V | Missense Mutation (SNP) | VAF 42/188 reads (22%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.833); catalogued as rs1225831017, COSV99305062; called by muse, mutect2, varscan2
- POLQ | c.7561A>G p.K2521E | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs1426603372, COSV99952374; called by muse, mutect2, varscan2
- PON3 | c.817G>T p.D273Y | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99672308; called by muse, mutect2, varscan2
- PPIAL4G | c.464A>T p.K155M | Missense Mutation (SNP) | VAF 30/274 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.752); catalogued as COSV101344010; called by muse, mutect2
- PPP1CA | c.647G>A p.W216* | Nonsense Mutation (SNP) | VAF 28/73 reads (38%) | catalogued as COSV100334972; called by muse, mutect2, varscan2
- PREX2 | c.3274G>C p.D1092H | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV99907806; called by muse, mutect2, varscan2
- QRFPR | c.841C>A p.L281I | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV100543780; called by muse, mutect2, varscan2
- RAB34 | c.592T>G p.S198A | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as COSV99972747; called by muse, mutect2, varscan2
- RAB39A | c.89_90insT p.Q30Hfs*65 | Frame Shift Ins (INS) | VAF 9/38 reads (24%) | catalogued as COSV100269198; called by mutect2, pindel, varscan2
- RBL2 | c.1288C>T p.H430Y | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.341); catalogued as COSV100043725; called by muse, mutect2, varscan2
- RFPL3 | c.592A>G p.R198G (on ENST00000249007 / NM_001098535.1; = p.R169G on NM_006604.2) | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV99967123; called by muse, mutect2, varscan2
- RIPOR3 | c.1497A>T p.E499D | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV99246613; called by muse, mutect2, varscan2
- ROCK2 | c.742G>C p.D248H | Missense Mutation (SNP) | VAF 69/214 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99837496; called by muse, mutect2, varscan2
- RPS6KA3 | c.401A>G p.H134R | Missense Mutation (SNP) | VAF 64/83 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV101084442; called by muse, mutect2, varscan2
- SASS6 | c.1480A>G p.T494A | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV99790900; called by muse, mutect2, varscan2
- SATB2 | c.555G>C p.E185D | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99611464, COSV99611589; called by muse, mutect2, varscan2
- SCYL2 | c.1799A>G p.N600S | Missense Mutation (SNP) | VAF 71/182 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772589834, COSV100675214; called by muse, mutect2, varscan2
- SETD2 | c.5277G>T p.Q1759H | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV100339205; called by muse, mutect2, varscan2
- SLC2A9 | c.658G>T p.G220C | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53316113; called by muse, mutect2, varscan2
- SLC39A12 | c.1316A>G p.H439R | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.175); catalogued as rs994466090, COSV101070071, COSV101070128; called by muse, mutect2, varscan2
- SLC6A1 | c.554T>A p.M185K | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.31); PolyPhen benign (0.307); catalogued as COSV99822845; called by muse, mutect2, varscan2
- SLIT2 | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs368061718; called by muse, mutect2, varscan2
- SPANXC | c.236C>A p.P79H | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV100748682; called by muse, varscan2
- SPEF2 | c.4334C>T p.P1445L | Missense Mutation (SNP) | VAF 69/122 reads (57%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.873); catalogued as COSV100289121; called by muse, mutect2, varscan2
- SPTB | c.6490G>A p.D2164N | Missense Mutation (SNP) | VAF 81/140 reads (58%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100731142; called by muse, mutect2, varscan2
- SYNE1 | c.3569T>G p.V1190G (on ENST00000367255 / NM_182961.4; = p.V1197G on NM_033071.3) | Missense Mutation (SNP) | VAF 101/133 reads (76%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV99567362; called by muse, mutect2, varscan2
- SYT10 | c.1414G>A p.D472N | Missense Mutation (SNP) | VAF 52/214 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV99951520; called by muse, mutect2, varscan2
- TBX22 | c.466T>A p.Y156N | Missense Mutation (SNP) | VAF 41/57 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100960828; called by muse, mutect2, varscan2
- TFAP2D | c.148A>G p.T50A | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99145681; called by muse, mutect2, varscan2
- THBS2 | c.262G>T p.A88S | Missense Mutation (SNP) | VAF 62/78 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100827925; called by muse, mutect2, varscan2
- THSD7A | c.3725A>C p.N1242T | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.25); PolyPhen benign (0.045); catalogued as COSV101439758; called by muse, mutect2, varscan2
- TLR4 | c.479A>T p.N160I (on ENST00000355622 / NM_138554.5; = p.N120I on NM_003266.4) | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100790656; called by muse, mutect2, varscan2
- TLR4 | c.2006G>C p.R669T (on ENST00000355622 / NM_138554.5; = p.R629T on NM_003266.4) | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.119); catalogued as COSV100842614, COSV100842780; called by muse, mutect2, varscan2
- TOPBP1 | c.4252G>A p.G1418R | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99605420; called by muse, mutect2, varscan2
- TPH2 | c.542G>A p.G181E | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100422131; called by muse, mutect2, varscan2
- TRPM7 | c.5578T>A p.S1860T | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.073); catalogued as COSV100539942; called by muse, mutect2, varscan2
- TTC13 | c.766G>T p.G256* | Nonsense Mutation (SNP) | VAF 41/168 reads (24%) | catalogued as COSV100792941; called by muse, mutect2, varscan2
- TTN | c.91572A>C p.R30524S (on ENST00000591111; = p.R23100S on NM_003319.4) | Missense Mutation (SNP) | VAF 28/59 reads (47%) | PolyPhen probably damaging (0.996); catalogued as COSV100617088; called by muse, mutect2, varscan2
- UBXN4 | c.629G>C p.R210T | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV99739276; called by muse, mutect2, varscan2
- VWA8 | c.535G>C p.E179Q | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99864343; called by muse, mutect2, varscan2
- WSCD2 | c.1664T>C p.L555P | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.819); catalogued as COSV99774734; called by muse, mutect2, varscan2
- XPO6 | c.988G>C p.E330Q | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.163); catalogued as COSV100485090; called by muse, mutect2, varscan2
- ZGRF1 | c.1331A>G p.N444S | Missense Mutation (SNP) | VAF 47/89 reads (53%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV100005584; called by muse, mutect2, varscan2
- ZNF37A | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 10/151 reads (7%) | catalogued as COSV100697296; called by muse, mutect2
- ZNF462 | c.3790G>A p.A1264T | Missense Mutation (SNP) | VAF 140/347 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV99472296; called by muse, mutect2, varscan2
- ZNF804A | c.1045A>T p.S349C | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.533); catalogued as COSV100168343; called by muse, mutect2, varscan2
- APBB1 | c.1954del p.A652Lfs*34 | Frame Shift Del (DEL) | VAF 24/63 reads (38%) | called by mutect2, pindel, varscan2
- CAMK2G | c.1292_1294del p.I431del (on ENST00000423381 / NM_001367518.1; = p.I368del on NM_001222.4 and 2 other RefSeq transcripts) | In Frame Del (DEL) | VAF 34/93 reads (37%) | called by mutect2, pindel, varscan2
- GRM6 | c.2119del p.L707Cfs*6 | Frame Shift Del (DEL) | VAF 15/32 reads (47%) | called by mutect2, pindel, varscan2
- PLEKHM1 | c.2008del p.T670Hfs*41 | Frame Shift Del (DEL) | VAF 35/114 reads (31%) | called by mutect2, pindel, varscan2
- TP53 | c.104dup p.L35Ffs*8 | Frame Shift Ins (INS) | VAF 114/237 reads (48%) | called by mutect2, pindel, varscan2
- ULK3 | c.290dup p.D98Rfs*14 | Frame Shift Ins (INS) | VAF 33/116 reads (28%) | called by mutect2, pindel, varscan2
- ADAM21 | c.648G>A p.V216= | Silent (SNP) | VAF 27/63 reads (43%) | catalogued as COSV99961089; called by muse, mutect2, varscan2
- ANK3 | c.12744T>C p.F4248= (on ENST00000280772 / NM_001320874.2; = p.F872= on NM_001149.3) | Silent (SNP) | VAF 60/186 reads (32%) | catalogued as COSV99780408; called by muse, mutect2, varscan2
- ARF5 | c.496C>T p.L166= | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as rs562589316, COSV99133802; called by muse, mutect2, varscan2
- ARHGAP28 | c.1878G>T p.L626= (on ENST00000383472 / NM_001366230.1; = p.L467= on NM_001010000.3) | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as rs768352309, COSV99151034; called by muse, mutect2, varscan2
- ATRNL1 | c.1737C>G p.V579= | Silent (SNP) | VAF 105/309 reads (34%) | catalogued as COSV100745728; called by muse, mutect2, varscan2
- BAHCC1 | c.3312A>C p.S1104= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV100311727; called by muse, mutect2, varscan2
- CAMKK2 | c.1296G>A p.E432= | Silent (SNP) | VAF 70/211 reads (33%) | catalogued as rs1316676688, COSV100243023; called by muse, mutect2, varscan2
- CBLIF | c.633C>T p.S211= | Silent (SNP) | VAF 42/118 reads (36%) | catalogued as COSV99950984; called by muse, mutect2, varscan2
- CD300LG | c.501G>T p.P167= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV99517450; called by muse, mutect2, varscan2
- DVL3 | c.651C>T p.H217= | Silent (SNP) | VAF 32/74 reads (43%) | catalogued as COSV100493694; called by muse, mutect2, varscan2
- FAM135B | c.2286G>T p.V762= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as COSV52708936, COSV99424681; called by muse, varscan2
- FZD7 | c.771G>A p.V257= | Silent (SNP) | VAF 63/198 reads (32%) | catalogued as rs1229740696, COSV99637253; called by muse, mutect2, varscan2
- GCC2 | c.2829G>A p.L943= | Silent (SNP) | VAF 63/183 reads (34%) | catalogued as rs1286683427, COSV100565491; called by muse, mutect2, varscan2
- HOXD12 | c.33T>C p.Y11= | Silent (SNP) | VAF 46/139 reads (33%) | catalogued as COSV101184287; called by muse, mutect2, varscan2
- IGKV1-8 | c.33G>T p.L11= | Silent (SNP) | VAF 60/204 reads (29%) | called by muse, mutect2, varscan2
- KCTD18 | c.42C>T p.L14= | Silent (SNP) | VAF 24/81 reads (30%) | catalogued as COSV100728899; called by muse, mutect2, varscan2
- LAMP5 | c.459C>T p.F153= | Silent (SNP) | VAF 48/104 reads (46%) | catalogued as COSV99855414; called by muse, mutect2, varscan2
- MAP2 | c.4611G>A p.K1537= | Silent (SNP) | VAF 56/147 reads (38%) | catalogued as COSV99560397; called by muse, mutect2, varscan2
- MUC16 | c.11487C>G p.P3829= | Silent (SNP) | VAF 79/200 reads (40%) | catalogued as COSV101200140; called by muse, mutect2, varscan2
- MYH15 | c.5187T>C p.Y1729= | Silent (SNP) | VAF 83/237 reads (35%) | catalogued as COSV99843456; called by muse, mutect2, varscan2
- NBEAL1 | c.5601A>G p.E1867= | Silent (SNP) | VAF 67/213 reads (31%) | catalogued as COSV101495716; called by muse, mutect2, varscan2
- OR10G4 | c.477C>A p.T159= | Silent (SNP) | VAF 100/288 reads (35%) | catalogued as COSV100304856; called by muse, mutect2, varscan2
- OR13G1 | c.235C>T p.L79= | Silent (SNP) | VAF 46/76 reads (61%) | catalogued as rs1463464865, COSV100687312; called by muse, mutect2, varscan2
- OR2L13 | c.48G>A p.L16= | Silent (SNP) | VAF 165/281 reads (59%) | catalogued as COSV100813778, COSV63560073; called by muse, mutect2, varscan2
- OR4A16 | c.399C>A p.I133= | Silent (SNP) | VAF 77/194 reads (40%) | catalogued as rs751496770, COSV100125267; called by muse, mutect2, varscan2
- OR51E1 | c.798T>C p.F266= | Silent (SNP) | VAF 62/112 reads (55%) | catalogued as rs1264278332, COSV101211519; called by muse, mutect2, varscan2
- OSBP | c.349C>T p.L117= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs557077830, COSV99803042; called by muse, varscan2
- PDF | c.411C>A p.P137= | Silent (SNP) | VAF 13/13 reads (100%) | catalogued as COSV99846539; called by muse, mutect2, varscan2
- PGM5 | c.1401G>A p.G467= | Silent (SNP) | VAF 56/151 reads (37%) | catalogued as COSV101123951; called by muse, mutect2, varscan2
- POLK | c.261C>T p.D87= | Silent (SNP) | VAF 22/33 reads (67%) | catalogued as rs755004522, COSV99606031; called by muse, mutect2, varscan2
- PRKDC | c.6483G>T p.A2161= | Silent (SNP) | VAF 26/53 reads (49%) | catalogued as rs761604517, COSV100038376, COSV100041023; called by muse, mutect2, varscan2
- SORCS1 | c.1284A>G p.Q428= | Silent (SNP) | VAF 29/85 reads (34%) | catalogued as rs753043519, COSV53873607, COSV99543230; called by muse, mutect2, varscan2
- SPANXC | c.237C>A p.P79= | Silent (SNP) | VAF 24/94 reads (26%) | catalogued as COSV100748680; called by muse, varscan2
- SPON1 | c.1305T>C p.D435= | Silent (SNP) | VAF 41/73 reads (56%) | catalogued as COSV100116048; called by muse, mutect2, varscan2
- SRRM2 | c.2952G>T p.P984= | Silent (SNP) | VAF 89/276 reads (32%) | catalogued as COSV100070960; called by muse, mutect2, varscan2
- UBR5 | c.1434C>T p.C478= | Silent (SNP) | VAF 29/88 reads (33%) | catalogued as COSV99641129; called by muse, mutect2, varscan2
- ZNF329 | c.513C>G p.G171= | Silent (SNP) | VAF 37/77 reads (48%) | catalogued as COSV100798754; called by muse, mutect2, varscan2
- ZNF831 | c.3432C>A p.P1144= | Silent (SNP) | VAF 33/97 reads (34%) | catalogued as COSV100926076; called by muse, mutect2, varscan2
- ZP1 | c.624G>C p.L208= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as COSV99612528; called by muse, mutect2, varscan2
- CDKL1 | n.59C>G | RNA (SNP) | VAF 4/41 reads (10%) | called by muse, mutect2, varscan2
- OR2W5 | n.914C>T | RNA (SNP) | VAF 45/174 reads (26%) | catalogued as rs1416762473; called by muse, mutect2, varscan2
- PTN | c.-31G>A | 5'UTR (SNP) | VAF 9/49 reads (18%) | catalogued as COSV100780895; called by muse, mutect2, varscan2
- RPL7P3 | chr20:62570581 G>C | 5'Flank (SNP) | VAF 11/59 reads (19%) | called by muse, mutect2, varscan2
- SNORD114-21 | n.13G>A | RNA (SNP) | VAF 49/99 reads (49%) | catalogued as rs1412473128; called by muse, mutect2, varscan2
